Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAEU, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAEU-01A (Primary Tumor).

Department of Pathology

ICD O-3

Seminoma NOS 9061/3

Site (R) Testis NOS C62.9

9/3/14

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Summary pathology report

Right orchidectomy; seminoma; diameter 6 cm; angio-invasion present; no invasion of tunica albuginea; epididymis free of tumor; surgical margin of spermatic cord free of tumor.

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

Source: NCI Genomic Data Commons file fc2a8bf6-7e4b-4a40-9475-8127166d3621 (TCGA-2G-AAEU-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).